Somatic mutation profile of tumor specimen TCGA-34-5927-01A (aliquot TCGA-34-5927-01A-11D-1817-08) from TCGA case TCGA-34-5927, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.8 years (25,857 days).
Specimen TCGA-34-5927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84c406dc-a2e8-4c22-8eea-c51ba25518dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5927-10A (Blood Derived Normal), aliquot TCGA-34-5927-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/961c07ab-07c4-4cdd-888e-24f9fa3c1968

The open-access MAF lists 291 somatic variants for this specimen: 219 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 66, Nonsense Mutation 12, Frame Shift Del 7, Frame Shift Ins 3, Intron 3, Splice Site 2, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.5332C>T p.R1778* | Nonsense Mutation (SNP) | VAF 50/67 reads (75%) | catalogued as rs794727176, CM030076, COSV61785134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAH | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62508731, CM043313, CM043315, COSV61020613; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 54/78 reads (69%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV60200553; called by muse, mutect2, varscan2
- ABCC2 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs574920702, COSV64984487; called by muse, mutect2, varscan2
- ACCS | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as COSV55459994; called by muse, mutect2, varscan2
- ACTL8 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64862789; called by muse, mutect2, varscan2
- ADAMTS15 | c.2602G>T p.G868C | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV54509983; called by muse, mutect2, varscan2
- ADAMTS20 | c.2960G>T p.R987M | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67139914; called by muse, mutect2, varscan2
- ADGRE2 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV59696505; called by muse, mutect2, varscan2
- AFF3 | c.2384A>G p.K795R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.772); catalogued as COSV57874466; called by muse, mutect2, varscan2
- AGTR2 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV64157118; called by muse, mutect2, varscan2
- AKAP17A | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV58312150; called by muse, mutect2, varscan2
- ALS2CL | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV59673873; called by muse, mutect2, varscan2
- AMER1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV57669552; called by muse, mutect2, varscan2
- AMHR2 | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV57687070; called by muse, mutect2, varscan2
- ANO4 | c.768C>G p.N256K (on ENST00000392977 / NM_001286615.2; = p.N221K on NM_178826.4) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV54614365; called by muse, mutect2, varscan2
- ANO4 | c.1311G>C p.W437C (on ENST00000392977 / NM_001286615.2; = p.W402C on NM_178826.4) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153592, COSV54614380; called by muse, mutect2, varscan2
- ANTXR1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58022349; called by muse, mutect2, varscan2
- APOB | c.7558C>T p.R2520* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs746483297, COSV51944824; called by muse, mutect2, varscan2
- APOL6 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as COSV68749776; called by muse, mutect2, varscan2
- ARAP2 | c.3264-1G>A p.X1088_splice | Splice Site (SNP) | VAF 22/32 reads (69%) | catalogued as COSV58292767; called by muse, mutect2, varscan2
- ARHGEF10 | c.925C>G p.H309D (on ENST00000398564; = p.H284D on NM_014629.4) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.095); catalogued as COSV50680370; called by muse, mutect2, varscan2
- ARNT2 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs1292214666, COSV57590751; called by muse, mutect2, varscan2
- ASAP2 | c.2447G>C p.S816T | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.197); catalogued as COSV55639114; called by muse, mutect2
- ASPM | c.3612G>T p.E1204D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV54139181; called by muse, mutect2, varscan2
- ASXL3 | c.6187A>G p.T2063A | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52480196; called by muse, varscan2
- ATP11A | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1340430612, COSV52125161; called by muse, mutect2, varscan2
- ATP8B4 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 89/240 reads (37%) | catalogued as COSV52724877; called by muse, mutect2, varscan2
- ATR | c.4232G>T p.S1411I | Missense Mutation (SNP) | VAF 91/348 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV63392857; called by muse, varscan2
- BEX1 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65580634; called by muse, mutect2, varscan2
- BICD2 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423989399, COSV100794118, COSV63551020; called by muse, mutect2, varscan2
- BRINP3 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs762844102, COSV66524577, COSV66542113; called by muse, mutect2, varscan2
- C11orf87 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV59358531; called by muse, mutect2, varscan2
- C2CD5 | c.2366T>A p.V789D | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV61727943; called by muse, mutect2, varscan2
- CALCR | c.968C>T p.A323V (on ENST00000649521 / NM_001164737.2; = p.A307V on NM_001742.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as rs527875590, COSV100810692, COSV64006212; called by muse, mutect2, varscan2
- CCDC185 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV64821975; called by muse, mutect2, varscan2
- CCR2 | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV52750251; called by muse, mutect2, varscan2
- CELSR2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV54779713; called by muse, mutect2, varscan2
- CEP41 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56221569; called by muse, mutect2, varscan2
- CEP89 | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV59867867; called by muse, mutect2, varscan2
- CHRD | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.151); catalogued as COSV52612697; called by muse, mutect2, varscan2
- CLDND1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761442781, COSV57860011; called by muse, mutect2, varscan2
- CLIP2 | c.2792G>T p.S931I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV56286630; called by muse, mutect2, varscan2
- COL11A1 | c.1801G>A p.G601R | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV62198617; called by muse, mutect2, varscan2
- COL19A1 | c.3098G>A p.R1033K | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1487895550, COSV59588534; called by muse, mutect2, varscan2
- COL5A2 | c.222A>G p.I74M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as rs1248370726, COSV66415626; called by muse, mutect2, varscan2
- CRNN | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 147/374 reads (39%) | catalogued as COSV55123983; called by muse, mutect2, varscan2
- CRYBG3 | c.7571G>A p.G2524E | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51716332; called by muse, mutect2, varscan2
- CSGALNACT2 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.312); catalogued as COSV65675477, COSV65676434; called by muse, mutect2, varscan2
- CSMD3 | c.7642C>A p.Q2548K (on ENST00000297405 / NM_001363185.1; = p.Q2444K on NM_052900.3) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV52178324, COSV52326829; called by muse, mutect2, varscan2
- CSMD3 | c.278G>A p.W93* | Nonsense Mutation (SNP) | VAF 90/217 reads (41%) | catalogued as COSV52145938, COSV99852544; called by muse, mutect2, varscan2
- CTIF | c.614A>T p.K205M | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV56492149; called by muse, mutect2, varscan2
- CUBN | c.3041C>A p.T1014K | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV64727781; called by muse, mutect2, varscan2
- CYP1A1 | c.1526A>T p.Q509L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV65698308; called by muse, mutect2, varscan2
- CYP8B1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs148690797; called by muse, mutect2, varscan2
- DCDC1 | c.4393T>A p.L1465M (on ENST00000597505 / NM_001367979.1; = p.L572M on NM_020869.3) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58003773; called by muse, mutect2, varscan2
- DENND4B | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs745566108, COSV100768326, COSV63412111; called by muse, mutect2, varscan2
- DIP2B | c.3503G>C p.G1168A | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56592584; called by muse, mutect2, varscan2
- DLD | c.119-2A>G p.X40_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as COSV52739832, COSV99227631; called by muse, mutect2, varscan2
- DNAH11 | c.13288G>A p.G4430R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275074212, COSV60982806; called by muse, mutect2, varscan2
- DNAJC4 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54175955; called by muse, mutect2, varscan2
- DOCK11 | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52248074; called by muse, mutect2, varscan2
- DPF2 | c.837C>G p.D279E | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV52891469; called by muse, mutect2, varscan2
- DRP2 | c.2229G>T p.L743F | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.879); catalogued as COSV65811925; called by muse, mutect2, varscan2
- DZANK1 | c.1078C>A p.L360I (on ENST00000262547 / NM_001099407.1; = p.L161I on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV52757315; called by muse, mutect2, varscan2
- EFCAB12 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.49); catalogued as COSV58179001; called by muse, mutect2, varscan2
- EFCAB13 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs144496511, COSV58946404; called by muse, mutect2, varscan2
- ELOVL3 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64175047; called by muse, mutect2
- ERCC1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 81/101 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV50004454, COSV50005600; called by muse, mutect2, varscan2
- ERCC4 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as COSV61314073; called by muse, mutect2, varscan2
- ETV3L | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.475); catalogued as COSV71901214; called by muse, mutect2, varscan2
- FAM135B | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs747996856, COSV52748628; called by muse, mutect2, varscan2
- FAP | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51867872; called by muse, mutect2, varscan2
- FBXO43 | c.1965G>C p.R655S | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV71055579; called by muse, mutect2, varscan2
- FLNC | c.7483C>A p.R2495S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV57965441, COSV57965964; called by muse, mutect2, varscan2
- FMN2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs747413802, COSV100146867, COSV60447753; called by muse, mutect2, varscan2
- GHRHR | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58198154; called by muse, mutect2, varscan2
- GOLGA3 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV52644117; called by muse, mutect2, varscan2
- GPR158 | c.2558C>A p.S853* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as COSV66283190; called by muse, mutect2, varscan2
- GPR37L1 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV66162824; called by muse, mutect2, varscan2
- GRAMD4 | c.1327A>T p.K443* | Nonsense Mutation (SNP) | VAF 75/196 reads (38%) | catalogued as COSV63032833; called by muse, mutect2, varscan2
- GRID1 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 117/183 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV60055047; called by muse, mutect2, varscan2
- HEPH | c.879C>A p.H293Q (on ENST00000343002; = p.H26Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57972802; called by muse, mutect2, varscan2
- HERC2 | c.5776C>T p.L1926F | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1319701825, COSV55351317; called by muse, mutect2, varscan2
- HS3ST4 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58831957; called by muse, mutect2
- INSC | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV65413311; called by muse, mutect2, varscan2
- KALRN | c.2437del p.R813Afs*7 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | catalogued as COSV53761733; called by mutect2, pindel, varscan2
- KCNA4 | c.1190C>A p.A397E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.639); catalogued as COSV60256100; called by muse, mutect2, varscan2
- KDM4A | c.2843G>C p.S948T | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV53520842; called by muse, mutect2
- KDR | c.3065G>C p.R1022P | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55760145, COSV55776827; called by muse, mutect2, varscan2
- KIAA1549L | c.1955C>A p.P652Q (on ENST00000321505; = p.P949Q on NM_012194.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV55771620; called by muse, mutect2, varscan2
- KIF11 | c.2971C>G p.L991V | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1267905506, COSV53274264; called by muse, mutect2, varscan2
- KIF17 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs762937507, COSV56122718; called by muse, mutect2, varscan2
- KIF21A | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62778348; called by muse, mutect2, varscan2
- KLF10 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs1313245610, COSV53436595; called by muse, mutect2, varscan2
- KLHL26 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); catalogued as rs1385020062, COSV56319817; called by muse, mutect2, varscan2
- KMT2D | c.6650G>A p.R2217H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1201197190, COSV56488862; called by muse, mutect2, varscan2
- KRTAP9-8 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 92/137 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54201071; called by muse, mutect2, varscan2
- LAX1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV65850191; called by muse, mutect2, varscan2
- LCE1A | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.799); catalogued as COSV58728058; called by muse, mutect2, varscan2
- LEF1 | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs761818179, COSV54473622; called by muse, mutect2, varscan2
- LLGL2 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs765413326, COSV51413976; called by muse, mutect2, varscan2
- LRATD1 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.53); PolyPhen benign (0.157); catalogued as COSV54472946, COSV54474272; called by muse, mutect2, varscan2
- LRBA | c.3160A>G p.I1054V | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV63965474; called by muse, mutect2, varscan2
- LRP2 | c.9154G>T p.D3052Y | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55575728; called by muse, mutect2, varscan2
- LRRC4C | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs376385641; called by muse, mutect2, varscan2
- LRRK2 | c.5978G>T p.R1993L | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54171770; called by muse, mutect2, varscan2
- LTA | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 107/136 reads (79%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV69305372; called by muse, mutect2, varscan2
- MAGEA3 | c.460del p.A154Lfs*13 | Frame Shift Del (DEL) | VAF 74/259 reads (29%) | catalogued as COSV64755775; called by mutect2, pindel, varscan2
- MAGI1 | c.2881G>A p.V961M (on ENST00000402939 / NM_001033057.2; = p.V989M on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs756412481, COSV58331718, COSV58345666; called by muse, mutect2, varscan2
- MAN1C1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56048953; called by muse, mutect2, varscan2
- MANEA | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs763972020, COSV62590670; called by muse, mutect2, varscan2
- MAP7D3 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60172682; called by muse, mutect2, varscan2
- MATN2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs759903117, COSV54719839; called by muse, mutect2, varscan2
- MC5R | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1002328102, COSV100228931, COSV61255817; called by muse, mutect2, varscan2
- MECOM | c.2752A>G p.T918A (on ENST00000468789 / NM_001105078.4; = p.T1106A on NM_004991.4) | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52975613; called by muse, mutect2, varscan2
- MECP2 | c.980C>A p.T327N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57657312; called by muse, mutect2, varscan2
- MECP2 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57657319; called by muse, mutect2, varscan2
- METTL25 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs770256096, COSV50262354; called by muse, mutect2, varscan2
- MN1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV56562486; called by muse, mutect2, varscan2
- MSR1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV50537449; called by muse, mutect2, varscan2
- NADSYN1 | c.116G>T p.R39I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as COSV59815210; called by muse, mutect2, varscan2
- NALCN | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs982821000, COSV51966921; called by muse, mutect2, varscan2
- NDUFB7 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV53109240; called by mutect2, varscan2
- NEBL | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV65806037; called by muse, mutect2, varscan2
- NIPAL2 | c.418A>T p.R140* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV57843617; called by muse, mutect2, varscan2
- NRK | c.3503A>G p.Y1168C | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV54607372; called by muse, mutect2
- NUP214 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV63913291; called by muse, mutect2, varscan2
- OR2M4 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV60709794; called by muse, mutect2, varscan2
- OR2T4 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63545190; called by muse, mutect2, varscan2
- OR52E2 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58613642; called by muse, mutect2, varscan2
- OR52E2 | c.270C>A p.N90K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs749286745, COSV100384542, COSV58613497; called by muse, mutect2, varscan2
- OR52E2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58613652; called by muse, mutect2, varscan2
- OR56A1 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57363955; called by muse, mutect2, varscan2
- OR56A1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as COSV57363601; called by muse, mutect2, varscan2
- OR8K5 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV57891367; called by muse, mutect2, varscan2
- OTOGL | c.1879G>A p.D627N (on ENST00000547103; = p.D618N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV101509519; called by muse, mutect2, varscan2
- OVCH1 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58968400; called by muse, mutect2
- PACS1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV57700172; called by muse, mutect2
- PALD1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 15/23 reads (65%) | catalogued as COSV54979185; called by muse, mutect2, varscan2
- PAPPA2 | c.2505G>T p.Q835H | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV62787203; called by muse, mutect2, varscan2
- PARD3B | c.1924G>C p.G642R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV62531785; called by muse, mutect2, varscan2
- PCDH8 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58815158; called by muse, mutect2, varscan2
- PCDH8 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.348); catalogued as COSV58815163; called by muse, mutect2, varscan2
- PCDHA3 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV63546303; called by muse, mutect2, varscan2
- PCSK9 | c.2038C>G p.R680G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53779142; called by muse, varscan2
- PDE10A | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 98/144 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); catalogued as rs751057729, COSV63106677; called by muse, mutect2, varscan2
- PEX7 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as COSV59252096; called by muse, mutect2, varscan2
- PHLPP1 | c.3949A>G p.K1317E | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.136); catalogued as COSV53039191; called by muse, mutect2, varscan2
- PLEK | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.534); catalogued as COSV52252865; called by muse, varscan2
- PLEK | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1288056554, COSV52251770; called by muse, varscan2
- PLXNC1 | c.994A>T p.R332* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV51584417; called by muse, mutect2, varscan2
- PMS2 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs587782513, COSV56220701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAME | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777374515, COSV67162277, COSV67162517; called by muse, mutect2, varscan2
- PRKDC | c.9641C>A p.P3214H | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV58064658; called by muse, mutect2, varscan2
- PRSS23 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV54707725; called by muse, mutect2, varscan2
- RAC1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61824236; called by muse, mutect2, varscan2
- RENBP | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60078061; called by muse, mutect2, varscan2
- REPIN1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101262577, COSV68293011; called by muse, mutect2, varscan2
- RGS9BP | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.603); catalogued as rs1321423167, COSV60136203; called by muse, mutect2
- RNF133 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV100411404, COSV57387212; called by muse, mutect2, varscan2
- RNF220 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 131/397 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62409956; called by muse, mutect2, varscan2
- RPS6KA2 | c.521A>T p.H174L | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55830908; called by muse, mutect2, varscan2
- RPS6KA2 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55830931; called by muse, mutect2, varscan2
- RSPO2 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52656510; called by muse, mutect2, varscan2
- RUSC1 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52742941; called by muse, mutect2, varscan2
- RYR3 | c.5461C>A p.H1821N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs766712025, COSV66809268; called by muse, mutect2, varscan2
- SALL3 | c.1919C>A p.S640Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV73306616; called by muse, varscan2
- SC5D | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV50613998; called by muse, mutect2, varscan2
- SCUBE1 | c.261del p.C87Wfs*78 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | catalogued as rs758676090; called by mutect2, pindel, varscan2
- SETD2 | c.4973C>T p.S1658L | Missense Mutation (SNP) | VAF 99/178 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV57436224, COSV57446986; called by muse, varscan2
- SEZ6L | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.093); catalogued as COSV50689888; called by muse, mutect2, varscan2
- SLC22A6 | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV64561165; called by muse, mutect2, varscan2
- SLC4A3 | c.2285T>C p.L762P | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56097768; called by muse, mutect2, varscan2
- SLC9A2 | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV52135441, COSV52138284; called by muse, mutect2, varscan2
- SON | c.2336G>C p.S779T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV51671141; called by muse, mutect2
- SPAG1 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52563614; called by muse, mutect2, varscan2
- SRCAP | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52669464; called by muse, mutect2, varscan2
- STAG2 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV54373098; called by muse, mutect2, varscan2
- SYNPO2 | c.3705G>T p.M1235I | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV61117854; called by muse, mutect2, varscan2
- SYT9 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59625498; called by muse, mutect2
- TCTN2 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs757163495, COSV57635148; called by muse, mutect2, varscan2
- TENM1 | c.7343C>A p.P2448H | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV64444067; called by muse, mutect2, varscan2
- TET2 | c.1836dup p.G613Wfs*25 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | catalogued as rs1480674896; called by mutect2, pindel, varscan2
- TIGD3 | c.1174T>C p.F392L | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as COSV52891474; called by muse, mutect2, varscan2
- TMBIM1 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV51466173; called by muse, mutect2, varscan2
- TRAPPC10 | c.3019G>T p.V1007L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV52377253, COSV52381745; called by muse, mutect2, varscan2
- TRGC2 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs779105825; called by muse, mutect2, varscan2
- TSBP1 | c.887G>T p.G296V (on ENST00000617061; = p.G299V on NM_006781.5) | Missense Mutation (SNP) | VAF 260/350 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV66660940; called by muse, mutect2, varscan2
- TTC39B | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 79/107 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as COSV52617146; called by muse, mutect2, varscan2
- TTLL4 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV51439657; called by muse, mutect2, varscan2
- TTN | c.96370G>A p.E32124K (on ENST00000591111; = p.E24700K on NM_003319.4) | Missense Mutation (SNP) | VAF 78/208 reads (38%) | PolyPhen probably damaging (0.995); catalogued as COSV60363049; called by muse, mutect2, varscan2
- TTN | c.84698G>C p.R28233T (on ENST00000591111; = p.R20809T on NM_003319.4) | Missense Mutation (SNP) | VAF 92/240 reads (38%) | PolyPhen probably damaging (0.996); catalogued as COSV60363076; called by muse, mutect2, varscan2
- UNC80 | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55907174; called by muse, mutect2, varscan2
- USP15 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 185/501 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); catalogued as COSV54799267; called by muse, mutect2, varscan2
- WDR44 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV54169386; called by muse, mutect2, varscan2
- WEE1 | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV55198478; called by muse, mutect2, varscan2
- XIAP | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV63024000; called by muse, mutect2, varscan2
- ZIC3 | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54977281; called by muse, mutect2, varscan2
- ZMYM2 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV67037816; called by muse, mutect2, varscan2
- ZMYM2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); catalogued as COSV67037819; called by muse, varscan2
- ZMYM2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67037823; called by muse, varscan2
- ZMYM2 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV67037830; called by muse, varscan2
- ZNF133 | c.694C>A p.H232N (on ENST00000316358 / NM_001352454.2; = p.H231N on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.452); catalogued as COSV60368187; called by muse, mutect2, varscan2
- ZNF208 | c.1993T>A p.Y665N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68112847; called by muse, varscan2
- ZNF236 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763298466, COSV53498275; called by muse, mutect2, varscan2
- ZNF254 | c.1442A>T p.K481M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61644982; called by muse, mutect2, varscan2
- ZNF407 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV55271024; called by muse, mutect2, varscan2
- ZNF681 | c.88A>T p.R30W | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68075809; called by muse, mutect2, varscan2
- ZNF774 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV62981110; called by muse, mutect2, varscan2
- ZNF804B | c.3072C>G p.N1024K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100303209, COSV60856739; called by muse, mutect2, varscan2
- ZNF835 | c.1284C>A p.S428R | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); catalogued as COSV101606418, COSV73379769; called by muse, mutect2, varscan2
- C2orf16 | c.343del p.I115Sfs*7 | Frame Shift Del (DEL) | VAF 35/100 reads (35%) | called by mutect2, pindel, varscan2
- CNN2 | c.901_902del p.P301Lfs*72 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- CRB1 | c.523_524del p.V175Pfs*14 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by pindel, varscan2
- GRM5 | c.1976del p.Y659Sfs*5 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- NR1I2 | c.1147dup p.Q383Pfs*5 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel
- PIK3R1 | c.1072_1076dup p.A360Efs*15 (on ENST00000521381 / NM_181523.3; = p.A90Efs*15 on NM_181504.4) | Frame Shift Ins (INS) | VAF 17/35 reads (49%) | called by mutect2, pindel, varscan2
- ACSM2B | c.1392T>C p.D464= | Silent (SNP) | VAF 169/723 reads (23%) | catalogued as COSV61660057; called by muse, mutect2, varscan2
- ACSM5 | c.1266T>A p.R422= | Silent (SNP) | VAF 74/228 reads (32%) | catalogued as COSV59375175; called by muse, mutect2, varscan2
- ADGRD1 | c.1662C>G p.V554= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV55458138; called by muse, mutect2, varscan2
- AKR1D1 | c.148C>A p.R50= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as CM097184, COSV54341071; called by muse, mutect2, varscan2
- ALPK1 | c.975G>A p.L325= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV51584344; called by muse, mutect2, varscan2
- AMER3 | c.105C>A p.G35= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58470468; called by muse, mutect2, varscan2
- ARMH4 | c.1653G>A p.E551= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as COSV50774790; called by muse, mutect2, varscan2
- BTK | c.957G>C p.V319= | Silent (SNP) | VAF 24/478 reads (5%) | catalogued as COSV58123923; called by muse, mutect2
- CDH23 | c.573G>T p.R191= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as COSV54953722; called by muse, mutect2, varscan2
- CDS1 | c.306G>A p.L102= | Silent (SNP) | VAF 55/88 reads (63%) | catalogued as COSV55690281; called by muse, mutect2, varscan2
- COL1A2 | c.2121T>A p.P707= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV51966486; called by muse, mutect2, varscan2
- COL9A2 | c.843C>T p.D281= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs140305893, COSV65607455; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPEB1 | c.978C>A p.L326= (on ENST00000617958; = p.L266= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV55621721, COSV55621883; called by muse, mutect2, varscan2
- CYB5R3 | c.618G>T p.L206= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs748177036, COSV61546721; called by muse, mutect2, varscan2
- CYP3A4 | c.483G>A p.R161= | Silent (SNP) | VAF 68/221 reads (31%) | catalogued as rs575568074, COSV60504383; called by muse, mutect2, varscan2
- CYRIB | c.777T>C p.G259= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV67833404; called by muse, mutect2, varscan2
- DCUN1D2 | c.732A>G p.V244= | Silent (SNP) | VAF 204/498 reads (41%) | catalogued as COSV60262706; called by muse, mutect2, varscan2
- EPHB1 | c.1578G>T p.L526= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV67666406; called by muse, mutect2, varscan2
- FARP2 | c.828G>A p.K276= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as rs189731640, COSV50874245, COSV50882398; called by muse, mutect2, varscan2
- FOXR2 | c.447C>A p.P149= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV59259813; called by muse, mutect2, varscan2
- GON4L | c.399A>G p.K133= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV55204801; called by muse, mutect2
- HOOK1 | c.1098A>T p.A366= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV64621054; called by muse, mutect2, varscan2
- IGHV3-23 | c.81G>A p.G27= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- IGSF21 | c.765C>T p.N255= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as COSV52145086; called by muse, mutect2, varscan2
- IL12RB1 | c.420G>A p.E140= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs368411705, COSV59099563; called by muse, mutect2, varscan2
- KBTBD3 | c.1095A>G p.S365= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as rs1189524098, COSV73241643; called by muse, mutect2, varscan2
- KIF11 | c.2841C>G p.L947= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV53274257; called by muse, mutect2, varscan2
- KIF19 | c.1029C>A p.A343= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV63430681; called by muse, mutect2
- MECOM | c.2751G>T p.V917= (on ENST00000468789 / NM_001105078.4; = p.V1105= on NM_004991.4) | Silent (SNP) | VAF 55/273 reads (20%) | catalogued as COSV52975632; called by muse, mutect2, varscan2
- MTA3 | c.417A>G p.S139= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV68136817; called by muse, mutect2, varscan2
- NR3C1 | c.1572G>T p.T524= | Silent (SNP) | VAF 68/123 reads (55%) | catalogued as COSV51546745; called by muse, mutect2, varscan2
- OPHN1 | c.2115C>T p.H705= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV62787172; called by muse, mutect2, varscan2
- OR10G7 | c.108T>C p.T36= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV57868952; called by muse, mutect2, varscan2
- OR56A4 | c.453C>A p.A151= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV58111765; called by muse, mutect2, varscan2
- OR5H2 | c.732C>A p.S244= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs769657343, COSV62351935; called by muse, mutect2, varscan2
- PCDHA6 | c.786C>T p.I262= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs782226224, COSV65350000; called by muse, mutect2, varscan2
- PCDHGA11 | c.1098G>T p.V366= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV54038199; called by muse, mutect2
- PIK3CD | c.1845G>A p.L615= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs752731457, COSV63132031; called by muse, mutect2, varscan2
- PLCB4 | c.2466A>G p.T822= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV53819396; called by muse, mutect2, varscan2
- PLXNA4 | c.3099C>G p.V1033= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV58161944; called by muse, mutect2, varscan2
- PPP1R12A | c.1395A>T p.A465= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV54114375; called by muse, mutect2, varscan2
- PRDM5 | c.1743T>A p.A581= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV53365374, COSV53368211; called by muse, mutect2, varscan2
- PTCD3 | c.1602C>A p.L534= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV54483614; called by muse, mutect2, varscan2
- RIPOR3 | c.936G>A p.V312= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV50405638; called by muse, mutect2, varscan2
- RNF19A | c.1128T>G p.A376= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV61994883; called by muse, mutect2, varscan2
- SALL2 | c.3015G>A p.T1005= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as rs916326111, COSV58105955; called by muse, mutect2, varscan2
- SELENOV | c.726C>G p.S242= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV59064919; called by muse, mutect2, varscan2
- SF3B3 | c.3399G>A p.T1133= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as rs199732910, COSV56791246; called by muse, mutect2, varscan2
- SLC10A3 | c.1164G>T p.V388= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV54837645; called by muse, mutect2, varscan2
- SLC25A20 | c.816G>A p.V272= | Silent (SNP) | VAF 56/91 reads (62%) | catalogued as COSV59804797; called by muse, mutect2, varscan2
- SLFN11 | c.885C>T p.F295= | Silent (SNP) | VAF 129/172 reads (75%) | catalogued as COSV57700434; called by muse, mutect2, varscan2
- SLITRK3 | c.2100C>T p.G700= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV53853152; called by muse, mutect2, varscan2
- SNX29 | c.504G>A p.L168= | Silent (SNP) | VAF 76/186 reads (41%) | catalogued as COSV60071133, COSV60072136; called by muse, mutect2, varscan2
- SPATA31A1 | c.3741C>T p.P1247= | Silent (SNP) | VAF 82/292 reads (28%) | called by mutect2, varscan2
- TCN1 | c.684T>A p.I228= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV57254796; called by muse, mutect2, varscan2
- TECTA | c.6087C>T p.F2029= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV50810070; called by muse, mutect2, varscan2
- TENM3 | c.5712C>A p.T1904= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV69319980; called by muse, mutect2, varscan2
- TGIF2LX | c.414C>A p.T138= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV52215265, COSV52215314; called by muse, mutect2, varscan2
- TMEM82 | c.112T>C p.L38= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV53818612; called by muse, mutect2, varscan2
- TRAF3IP3 | c.675G>A p.L225= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV50561241; called by muse, mutect2, varscan2
- ZBTB20 | c.570G>A p.T190= (on ENST00000474710 / NM_001164342.2; = p.T117= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs752505202, COSV61845221; called by muse, mutect2, varscan2
- ZMYM2 | c.591G>A p.V197= | Silent (SNP) | VAF 123/453 reads (27%) | catalogued as COSV67037826; called by muse, varscan2
- ZMYM3 | c.1509C>G p.T503= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as COSV58740897; called by muse, varscan2
- ZNF486 | c.327G>A p.L109= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV58722859; called by muse, mutect2, varscan2
- ZNF488 | c.588C>T p.L196= | Silent (SNP) | VAF 55/78 reads (71%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.604C>T p.L202= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs774990765, COSV52850951; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509317 C>A | 5'Flank (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- ANK2 | c.84+57060G>T | Intron (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52189851; called by muse, mutect2, varscan2
- COG5 | c.1686+1509G>A | Intron (SNP) | VAF 16/56 reads (29%) | catalogued as rs1448431490, COSV99773326; called by muse, mutect2, varscan2
- FAM183BP | n.1100G>T | RNA (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2, varscan2
- NCAPH2 | c.861+15G>T | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99410780; called by muse, mutect2, varscan2
- SAMD9L | c.*2A>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100561170; called by muse, mutect2, varscan2
